Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8161, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8161-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med: Rec.:

Phone Number:

DOB: [REDACTED]

Client: [REDACTED]

Gender: F

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

[REDACTED]

=====

CLINICAL HISTORY

[REDACTED] woman has episodic right arm symptoms, and on imaging there are multiple left frontal and parietal lobes subcortical lesions, the larger one in the left posterior parietal area. There is focal mild enhancement.

OPERATIVE DIAGNOSES

A, B: Brain lesion; left parietal mass

[REDACTED] TCGA-DU-8161

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, sites not specified, biopsy and excision:

1. Oligoastrocytoma, anaplastic.
2. MIB-1 proliferation index: 22%.
- See Microscopy Description and Comment.

COMMENT

The specimen is portions of cerebrum that are extensively infiltrated and

focally effaced by a glial neoplastic proliferation. The neoplastic cells

have moderate nuclear pleomorphism, and tend to grow along the Virchow-Robin

space. There is brisk mitotic activity focally, and the MIB-1 proliferation

index is about 20% in several more active areas. There is neovascularization,

but there is no clear microvascular proliferation.

Part A is several fragments of cerebrum, with infiltrating neoplasm in

[page 2 of 6]
a couple of them. The neoplasm in this specimen has more of an oligodendroglial phenotype. Part B is a large portion of solid tumor. The neoplasm here has an astrocytic phenotype.

The findings are interpreted as those of an anaplastic mixed oligoastrocytoma.

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED]

[page 3 of 6]
Interpretation

There is loss of heterozygosity in two telomeric loci D1S548 and D1S1612 detected on chromosome arm 1p. These findings are suggestive of partial deletion of chromosome arm 1p

There is no evidence of allelic loss on chromosome arm 19q.

Informative loci are: D1S548, D1S552, D1S468, D1S1612, D1S496, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block and a corresponding blood specimen.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[page 4 of 6]
[REDACTED]

Addendum Diagnosis
EGFRvIII Mutation Assay

NEGATIVE No evidence of EGFRvIII mutation is detected

Test Description:

Testing performed on RNA extracted from paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is often amplified, overexpressed, and/or mutated

in up to 40% to 50% of patients. EGFR variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR resulting from deletion of exons

2-7, which is commonly expressed in glioblastoma. Cell culture and in vivo

models of glioblastoma have demonstrated EGFRvIII as defining prognostically

distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII

has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the

tumor suppressor protein PTEN is intact.

RNA is extracted from formalin fixed, paraffin embedded tissue samples and

reverse transcribed to cDNA. The cDNA is then amplified using standard PCR

technique for DNA templates including the housekeeping genes for testing RNA

integrity. PCR products are detected by gel electrophoresis. The limit of

detection of this assay has been determined to be approximately 5 mutant cells

in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED]

[REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or

approved for specific uses by the U.S. Food and Drug Administration (FDA). The

FDA has determined that such clearance or approval is not necessary. These

results are provided for informational purposes only, and should be

[page 5 of 6]
interpreted only in the context of established procedures and/or
diagnostic
criteria.

=====

INTRA-OPERATIVE CONSULTATION

A.
Brain, excision biopsy:
1. Touch prep and smears: Glial neoplasm. Touch preparation
smears
performed at and results reported to the Physician
of
Record.
2. Frozen sections: Cerebral cortex and white matter, not
diagnostic.
Frozen section performed at and results reported
to the
Physician of Record.

GROSS DESCRIPTION

A. Brain, excision biopsy: FIXATIVE: Fresh. NO. PIECES: many tan
pink gray
soft tissue fragments. SIZE/VOL: 20x20x4 mm aggregate. CASSETTES:
A1- Frozen
section remnants, A2-3 remaining.

B. Brain, excision biopsy: FIXATIVE: Fresh. NO. PIECES: 2 pink tan
soft
tissue. SIZE/VOL: 20x6x4 mm. CASSETTES: B1, NS.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: Performed on part B. There is prominent
gliofibrillogenesis by neoplastic cells. Synaptophysin and NeuN are
essentially negative. About one third of neoplastic cells over
express
strongly the p53 protein. The CD34 depicts focal neovascularization,
but no
clear microvascular cellular proliferation. With the MIB-1 there is a
proliferation index of about 20%, in several more active areas of the
neoplasm.

[page 6 of 6]
ICD-9(s):
225.0 225.0

Histo Data

Part A: Brain excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

Part B: Brain excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
CD34-DA x 1	1		EGFR-MOLECULAR,

also.

Thanks.

mGFAP-DA x 1

1

H/E x 1

1

MGMT x 1

1

LOH also.

MOLECULAR.

Thanks.

MIB1-DA x 1

1

NeuN x 1

1

P53DO7 x 1

1

Synap-DA x 1

1

*** End of Report ***

Source: NCI Genomic Data Commons file 34a1fb6e-8d75-4177-805b-71801caa65d7 (TCGA-DU-8161.867DAA2D-0B54-4AC8-9203-EA592EA23953.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).